Somatic mutation profile of tumor specimen 0DL0JA from CCDI case PBBXKY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 9.1 years (3,331 days).
Specimen 0DL0JA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e2ad0e7-b65a-481e-9668-ab9d0b0dafe6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL0IR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a92fab6b-65db-4683-b239-440e3da7eed8

The open-access MAF lists 37 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, Intron 3, Nonsense Mutation 2, Splice Site 2, Splice Region 1, Frame Shift Del 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 281/751 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.3113+1G>T p.X1038_splice | Splice Site (SNP) | VAF 320/768 reads (42%) | catalogued as rs267606599, CS031789, CS951480, COSV62192529, COSV62198325, COSV62207085; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.831T>G p.C277W | Missense Mutation (SNP) | VAF 35/942 reads (4%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as CM065496, COSV52676368, COSV52783531, COSV53164903; called by muse, mutect2
- DGKK | c.3291G>C p.K1097N | Missense Mutation (SNP) | VAF 229/1018 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV65707075; called by muse, mutect2, varscan2
- ELF2 | c.1393A>G p.T465A (on ENST00000379550 / NM_001331036.2; = p.T405A on NM_006874.4) | Missense Mutation (SNP) | VAF 48/824 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs536472282; called by muse, mutect2
- HECW1 | c.1567C>A p.Q523K | Missense Mutation (SNP) | VAF 29/670 reads (4%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV101224571; called by muse, mutect2
- HTR5A | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 319/1169 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs746290830, COSV55285522, COSV99839814; called by muse, mutect2, varscan2
- ITGA3 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 26/617 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV99143400; called by muse, mutect2
- NF1 | c.204+2T>G p.X68_splice | Splice Site (SNP) | VAF 209/547 reads (38%) | catalogued as CS000868; called by muse, mutect2, varscan2
- NXPE4 | c.812A>G p.E271G | Missense Mutation (SNP) | VAF 74/1548 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs374528575; called by muse, mutect2
- OR4X2 | c.350C>G p.A117G | Missense Mutation (SNP) | VAF 22/634 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56583175; called by muse, mutect2
- PHKA2 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 68/653 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM078504, COSV66055972; called by muse, varscan2
- SCUBE1 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 189/779 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV62610734; called by muse, mutect2, varscan2
- TENT5D | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 266/651 reads (41%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs768296665, COSV57639667; called by muse, mutect2, varscan2
- TP53 | c.136dup p.S46Ffs*6 | Frame Shift Ins (INS) | VAF 203/537 reads (38%) | catalogued as COSV53295176; called by mutect2, pindel, varscan2
- ATF7IP | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 56/1100 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); called by muse, mutect2
- CEP162 | c.3345A>C p.R1115S | Missense Mutation (SNP) | VAF 318/1212 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHPF | c.85del p.L29Sfs*96 | Frame Shift Del (DEL) | VAF 135/657 reads (21%) | called by mutect2, pindel, varscan2
- EFCAB10 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 52/1204 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.082); called by muse, mutect2
- EYS | c.3733T>A p.C1245S | Missense Mutation (SNP) | VAF 52/972 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.036); called by muse, mutect2
- GABRA3 | c.1442G>T p.R481L | Missense Mutation (SNP) | VAF 77/958 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- KIF27 | c.2308C>T p.Q770* | Nonsense Mutation (SNP) | VAF 124/1680 reads (7%) | called by muse, mutect2
- MYL2 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 76/909 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.117); called by muse, mutect2
- NR1I3 | c.694+5G>C | Splice Region (SNP) | VAF 229/763 reads (30%) | called by muse, mutect2, varscan2
- RFX7 | c.895C>T p.Q299* (on ENST00000559447 / NM_001368074.1; = p.Q396* on NM_022841.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 97/905 reads (11%) | called by muse, mutect2, varscan2
- USP38 | c.2008G>T p.D670Y | Missense Mutation (SNP) | VAF 68/892 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.436); called by muse, mutect2
- ARHGAP36 | c.597A>T p.G199= | Silent (SNP) | VAF 54/1028 reads (5%) | called by muse, mutect2
- FAM71F2 | c.378G>A p.L126= | Silent (SNP) | VAF 81/843 reads (10%) | called by muse, mutect2, varscan2
- KRT38 | c.786C>T p.D262= | Silent (SNP) | VAF 62/898 reads (7%) | called by muse, mutect2
- LINGO2 | c.6T>C p.L2= | Silent (SNP) | VAF 54/925 reads (6%) | called by muse, mutect2
- MBD3L3 | c.264C>T p.C88= | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as rs1490155346; called by muse, mutect2, varscan2
- PRSS56 | c.1431G>A p.E477= | Silent (SNP) | VAF 114/466 reads (24%) | called by muse, mutect2, varscan2
- SULT1C3 | c.339G>A p.L113= | Silent (SNP) | VAF 262/1011 reads (26%) | catalogued as COSV61252466; called by muse, mutect2, varscan2
- ALDH1A1 | c.504+28A>G | Intron (SNP) | VAF 62/527 reads (12%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*4544G>T | 3'UTR (SNP) | VAF 60/854 reads (7%) | catalogued as COSV99950048; called by muse, mutect2
- LIAS | c.299+1465G>T | Intron (SNP) | VAF 172/799 reads (22%) | called by muse, mutect2, varscan2
- PHF19 | c.1305-80G>A | Intron (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
